Somatic mutation profile of tumor specimen 5ea22f5e-307b-491d-801f-8b7fa6 (aliquot 5ea22f5e-307b-491d-801f-8b7fa6_D6) from CPTAC case 01OV030, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 5ea22f5e-307b-491d-801f-8b7fa6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80373f75-257a-4ded-98e7-3215495413a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 907f990e-2b1a-49dc-8944-48e146 (Blood Derived Normal), aliquot 907f990e-2b1a-49dc-8944-48e146_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a83ccc0-443c-46d5-b67b-35711bdd7cde

The open-access MAF lists 64 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 17, Nonsense Mutation 4, Frame Shift Del 4, Intron 2, RNA 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.783-11_807del p.X261_splice | Splice Site (DEL) | VAF 82/173 reads (47%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCB1 | c.3068C>T p.T1023M | Missense Mutation (SNP) | VAF 49/589 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs142183184; called by muse, mutect2
- ASIC5 | c.1418G>A p.W473* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV101611192; called by muse, mutect2, varscan2
- CDS2 | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs569818585; called by muse, mutect2, varscan2
- CEP112 | c.1462A>G p.I488V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs755140327, COSV101210780; called by muse, mutect2, varscan2
- FAT3 | c.3581A>T p.N1194I | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565383654, COSV53118407; called by muse, mutect2, varscan2
- FSD1 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as rs961982251; called by muse, mutect2, varscan2
- GATA5 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 161/388 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs116503780, COSV53345049; called by muse, mutect2, varscan2
- GPR146 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 143/622 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.265); catalogued as rs769441333; called by muse, mutect2, varscan2
- GZMK | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs377736354; called by muse, mutect2, varscan2
- HAPLN1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.381); catalogued as rs753012193, COSV57151856; called by muse, mutect2, varscan2
- LRP10 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1003158657; called by muse, mutect2, varscan2
- NLRP14 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 44/257 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55069575; called by muse, mutect2, varscan2
- NT5M | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs535130047; called by muse, mutect2, varscan2
- PDZD8 | c.723G>A p.W241* | Nonsense Mutation (SNP) | VAF 48/319 reads (15%) | catalogued as rs1235867333; called by muse, mutect2, varscan2
- SDS | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777061581, COSV57452721; called by muse, mutect2, varscan2
- SPEG | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs1411322336; called by muse, varscan2
- SPHK2 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV99709442; called by muse, mutect2, varscan2
- STRIP2 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.15); catalogued as rs1231775240; called by muse, mutect2
- TMEM26 | c.814C>A p.R272S | Missense Mutation (SNP) | VAF 66/409 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53263573; called by mutect2, varscan2
- TRIM51 | c.1129C>A p.L377I | Missense Mutation (SNP) | VAF 192/468 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.04); catalogued as COSV99792383; called by mutect2, varscan2
- TSHZ3 | c.1910C>A p.P637Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV53683794; called by mutect2, varscan2
- TTN | c.20167C>T p.R6723* (on ENST00000591111; = p.R5796* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/240 reads (18%) | catalogued as rs576359448, COSV59929700, COSV60198630; called by muse, mutect2, varscan2
- AL645922.1 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 27/538 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.048); called by muse, mutect2
- CAMKV | c.1004C>G p.A335G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); called by muse, mutect2
- CNGA3 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- COL14A1 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DDX54 | c.1171A>G p.T391A | Missense Mutation (SNP) | VAF 107/463 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DHX36 | c.1169C>G p.T390S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- EVI2B | c.700A>C p.N234H | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2
- HSF4 | c.1032del p.R345Gfs*51 (on ENST00000521374 / NM_001040667.3; = p.R315Gfs*51 on NM_001538.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 59/345 reads (17%) | called by mutect2, pindel, varscan2
- IL1F10 | c.436T>G p.F146V | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- KLHL42 | c.1325T>A p.L442* | Nonsense Mutation (SNP) | VAF 61/373 reads (16%) | called by muse, mutect2, varscan2
- LRP10 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- NAV2 | c.3385C>A p.L1129I (on ENST00000396087 / NM_001244963.2; = p.L1106I on NM_145117.5) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- NT5DC3 | c.1174_1175del p.Y392Qfs*2 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by pindel, varscan2
- PKD1 | c.7052C>A p.A2351D | Missense Mutation (SNP) | VAF 90/461 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by mutect2, varscan2
- RASGRF1 | c.716_717del p.R239Qfs*13 | Frame Shift Del (DEL) | VAF 102/453 reads (23%) | called by pindel, varscan2
- SETD4 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIMELESS | c.2363T>G p.F788C | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TNFRSF21 | c.1197del p.P400Qfs*20 | Frame Shift Del (DEL) | VAF 27/135 reads (20%) | called by mutect2, pindel, varscan2
- U2AF1L4 | c.204_212del p.S70_V72del | In Frame Del (DEL) | VAF 16/130 reads (12%) | called by mutect2, pindel, varscan2
- USP9X | c.6804A>G p.I2268M | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF671 | c.884C>A p.T295N | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CAPN1 | c.1221G>A p.P407= | Silent (SNP) | VAF 11/164 reads (7%) | catalogued as rs1405889144; called by muse, mutect2
- CD79B | c.10C>T p.L4= | Silent (SNP) | VAF 81/361 reads (22%) | called by muse, mutect2, varscan2
- COL3A1 | c.2109C>T p.P703= | Silent (SNP) | VAF 50/400 reads (13%) | catalogued as rs746947080; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL9A3 | c.441C>T p.P147= | Silent (SNP) | VAF 34/346 reads (10%) | catalogued as rs41306378, COSV100673381; ClinVar: uncertain significance; called by muse, mutect2
- CTDP1 | c.1653G>A p.R551= | Silent (SNP) | VAF 57/251 reads (23%) | called by muse, mutect2, varscan2
- FBXO21 | c.1614C>T p.N538= (on ENST00000330622 / NM_033624.3; = p.N531= on NM_015002.3) | Silent (SNP) | VAF 25/168 reads (15%) | catalogued as rs1565996939; called by muse, mutect2, varscan2
- HSPA4 | c.1119T>G p.T373= | Silent (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- HYOU1 | c.1162C>A p.R388= | Silent (SNP) | VAF 48/250 reads (19%) | catalogued as COSV68216780; called by mutect2, varscan2
- KDM8 | c.1038A>C p.S346= | Silent (SNP) | VAF 94/236 reads (40%) | catalogued as rs751815669; called by mutect2, varscan2
- L3MBTL3 | c.748C>T p.L250= | Silent (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- LAMA3 | c.5493C>T p.N1831= (on ENST00000313654 / NM_198129.4; = p.N222= on NM_000227.6) | Silent (SNP) | VAF 76/371 reads (20%) | catalogued as rs199982757, COSV52542530; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYH4 | c.3600C>T p.H1200= | Silent (SNP) | VAF 51/230 reads (22%) | catalogued as COSV99701114, COSV99701369; called by muse, mutect2, varscan2
- PCDHA10 | c.1386C>T p.F462= | Silent (SNP) | VAF 178/545 reads (33%) | catalogued as rs987628518, COSV56510213; called by muse, mutect2, varscan2
- SH3RF3 | c.2484C>T p.Y828= | Silent (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- SPEF2 | c.1881G>A p.E627= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- TMEM38A | c.159G>A p.A53= | Silent (SNP) | VAF 22/179 reads (12%) | catalogued as rs142123915; called by muse, mutect2, varscan2
- ZFAT | c.2127G>A p.R709= | Silent (SNP) | VAF 47/318 reads (15%) | catalogued as rs766549112; called by muse, mutect2, varscan2
- ATXN7 | c.500-11984C>A | Intron (SNP) | VAF 57/145 reads (39%) | called by mutect2, varscan2
- FAM90A20P | n.972G>T | RNA (SNP) | VAF 110/638 reads (17%) | catalogued as rs757353635; called by mutect2, varscan2
- GNGT1 | c.-11-17A>G | Intron (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
